FM case AD3482 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/478e79a5-e4c3-493e-8008-7f9a85a37979

Male, 51.4 years: Non-small cell carcinoma (ICD-O-3 8046/3) of the lung; metastasis biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
